Somatic mutation profile of tumor specimen MP2PRT-PATSMV-TMP1-A (aliquot MP2PRT-PATSMV-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATSMV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,348 days).
Specimen MP2PRT-PATSMV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07b873fd-17c8-4b91-9f73-905c0c14b69d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATSMV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATSMV-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12e9b83c-889e-4bb4-b6f4-eb93db8c3054

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 76/229 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNND2 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 108/416 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58894961; called by muse, mutect2, varscan2
- PAK5 | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 159/353 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62022425; called by muse, mutect2, varscan2
- PRR23B | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 16/552 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1463442551, COSV61494743; called by muse, mutect2
- RIOX2 | c.1252C>T p.R418C (on ENST00000333396 / NM_001042533.2; = p.R417C on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs557264232; called by muse, mutect2, varscan2
- ANO4 | c.577C>G p.P193A (on ENST00000392977 / NM_001286615.2; = p.P158A on NM_178826.4) | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTPRS | c.3667G>A p.G1223S | Missense Mutation (SNP) | VAF 156/340 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLC1A7 | c.1014G>A p.A338= | Silent (SNP) | VAF 63/229 reads (28%) | catalogued as rs769608351, COSV65199268; called by muse, mutect2, varscan2
